Gene-level copy-number profile of tumor specimen TCGA-2G-AAGI-05A from TCGA case TCGA-2G-AAGI, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 33.9 years (12,366 days).
Specimen TCGA-2G-AAGI-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.dfedc902-d551-42c9-9644-da0cd6304565.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAGI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 399 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/85b86fb3-55c9-4fca-9cb8-e3721fc59d03

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2,391; copy number 2: 9,523; copy number 3: 23,807; copy number 4: 7,473; copy number 5: 9,649; copy number 6: 5,674; copy number 7: 1,095; copy number 8: 214; copy number 9: 396; copy number 10: 1; copy number 12: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAGI-05A-11D-A42X-01): tumor purity 0.29, ploidy 3.37, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:85,934,535–85,937,548, 1 gene: AC012511.2.
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.
- chr17:41,265,339–41,271,835, 2 genes (within-gene range 0–3): KRTAP9-6, KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,707 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:10,685,003–10,697,661, 1 gene, copy number 10 (within-gene range 3–10): AC084048.1.
- chr4:49,588,772–76,148,444, 395 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr5:36,192,589–36,302,114, 3 genes, copy number 8 (within-gene range 2–8): NADK2, NADK2-AS1, RANBP3L.
- chr8:23,841,929–24,912,073, 8 genes, copy number 7 (within-gene range 6–7): STC1, RNU1-148P, AC023202.1, ADAM28, AC120193.1, ADAMDEC1, ADAM7, AC024958.1.
- chr8:27,433,370–27,433,434, 1 gene, copy number 9: MIR6842.
- chr12:66,767–9,658,392, 343 genes, copy number 7 (within-gene range 0–7) (broad region; genes not listed).
- chr12:9,594,551–23,188,807, 284 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr12:23,529,504–34,249,958, 218 genes, copy number 7 (within-gene range 6–14) (broad region; genes not listed).
- chr16:78,890,231–78,892,302, 1 gene, copy number 12: AC027279.4.
- chr22:17,137,511–24,270,134, 453 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
